Somatic mutation profile of tumor specimen TCGA-EK-A2RE-01A (aliquot TCGA-EK-A2RE-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 26.7 years (9,743 days).
Specimen TCGA-EK-A2RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d5680e0-246f-467e-937a-0861f052b6db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RE-10A (Blood Derived Normal), aliquot TCGA-EK-A2RE-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c869e8d-a80c-4c3f-99cb-a91053655b40

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB7 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99504019; called by muse, mutect2
- FBXL2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs370862715; called by muse, mutect2, varscan2
- JAG1 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1346269262, COSV54758879; called by muse, mutect2, varscan2
- LRRFIP1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99790496; called by muse, mutect2
- NOD1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs201438430; called by muse, mutect2, varscan2
- NPTX1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as COSV60775544; called by muse, mutect2, varscan2
- PDE6C | c.2292G>T p.M764I | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101008606; called by muse, mutect2
- SUPT7L | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV53115591; called by muse, mutect2, varscan2
- TGFBR2 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM093626, COSV55452895; called by muse, mutect2, varscan2
- THSD7A | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as rs777727562, COSV69855816; called by muse, mutect2, varscan2
- TNFRSF21 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1280450012, COSV57283263; called by muse, mutect2, varscan2
- USP42 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs746488006, COSV60361601; called by muse, mutect2, varscan2
- MED1 | c.4572dup p.S1525Ifs*3 | Frame Shift Ins (INS) | VAF 41/117 reads (35%) | called by mutect2, pindel, varscan2
- SMURF2 | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZXDC | c.752C>A p.T251K | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ADGRL1 | c.4374G>A p.E1458= (on ENST00000340736 / NM_001008701.3; = p.E1453= on NM_014921.5) | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1315878214, COSV61565362; called by muse, mutect2, varscan2
- BATF2 | c.435T>A p.S145= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV57250282; called by muse, mutect2, varscan2
- CPSF2 | c.336A>T p.T112= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100102654; called by muse, mutect2, varscan2
- FGF18 | c.348C>T p.L116= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1191022226, COSV51127249; called by muse, mutect2, varscan2
- PDZD2 | c.6099C>T p.S2033= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs781506103, COSV56852694; called by muse, mutect2, varscan2
